Somatic mutation profile of tumor specimen HCM-BROD-0098-C15-06A (aliquot HCM-BROD-0098-C15-06A-01D-A79C-36) from HCMI case HCM-BROD-0098-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 77.3 years (28,226 days).
Specimen HCM-BROD-0098-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60d74a3c-8bfb-4b87-8ae8-e45afd166ea7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0098-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0098-C15-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cec6f20-9670-466a-8223-5521e4166f91

The open-access MAF lists 60 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 39, Silent 11, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 97/816 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs141306868; called by muse, varscan2
- ADGRL3 | c.674C>T p.A225V (on ENST00000506720 / NM_001322402.2; = p.A157V on NM_015236.6) | Missense Mutation (SNP) | VAF 225/402 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV72268675; called by muse, mutect2, varscan2
- COL11A1 | c.3292C>T p.Q1098* | Nonsense Mutation (SNP) | VAF 165/291 reads (57%) | catalogued as COSV62200904; called by muse, mutect2, varscan2
- DGKH | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 85/232 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs1044883165; called by muse, mutect2, varscan2
- DOCK10 | c.3961G>A p.G1321S | Missense Mutation (SNP) | VAF 88/113 reads (78%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.999); catalogued as rs748247508; called by muse, mutect2, varscan2
- GCKR | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 109/426 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as rs545938878, COSV53110688; called by muse, mutect2, varscan2
- KDM2B | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 203/517 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs574056393; called by muse, mutect2, varscan2
- LDLRAD4 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV63339457; called by muse, mutect2, varscan2
- LGR5 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 138/570 reads (24%) | catalogued as rs780252667, COSV57008615; called by muse, mutect2, varscan2
- MIB2 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 103/825 reads (12%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.811); catalogued as rs542893068; called by muse, mutect2, varscan2
- MR1 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1398906447, COSV51581544; called by muse, mutect2, varscan2
- MSTO1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 217/372 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs749541377, COSV55471139; called by muse, varscan2
- MYO9B | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 87/593 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV68276888; called by muse, mutect2, varscan2
- NLRP3 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 195/344 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs762512734, COSV60229623; called by muse, mutect2, varscan2
- NPBWR2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 303/734 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768578565, COSV63900751; called by muse, mutect2, varscan2
- NRXN3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 218/438 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777010458; called by muse, mutect2, varscan2
- PHOX2B | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 157/399 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs774521395, COSV56931267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIBF1 | c.1681G>A p.G561S | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959769608; called by muse, mutect2, varscan2
- PLXNA2 | c.363C>G p.Y121* | Nonsense Mutation (SNP) | VAF 108/437 reads (25%) | catalogued as COSV100885850; called by muse, mutect2, varscan2
- POGLUT3 | c.496del p.D166Ifs*14 | Frame Shift Del (DEL) | VAF 189/319 reads (59%) | catalogued as COSV60212178; called by mutect2, pindel, varscan2
- PRR16 | c.236C>T p.T79M (on ENST00000407149 / NM_001300783.2; = p.T56M on NM_016644.2) | Missense Mutation (SNP) | VAF 71/393 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201082218, COSV65394799; called by muse, mutect2, varscan2
- RBP3 | c.3204G>A p.W1068* | Nonsense Mutation (SNP) | VAF 67/264 reads (25%) | catalogued as rs1555211795; called by muse, mutect2, varscan2
- RNF183 | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 9/284 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52908439; called by muse, mutect2
- SH3D21 | c.602C>T p.A201V (on ENST00000453908 / NM_001162530.2; = p.A90V on NM_024676.5) | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as rs781589402, COSV100454375; called by muse, mutect2, varscan2
- TPO | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs777179599, COSV61095792; called by muse, mutect2, varscan2
- TSPEAR | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 112/280 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as rs782644109, COSV59976402; called by muse, mutect2, varscan2
- TTC6 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 207/657 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.344); catalogued as COSV73285272; called by muse, mutect2, varscan2
- ZAN | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 112/134 reads (84%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.515); catalogued as rs553925637, COSV61811373; called by muse, mutect2, varscan2
- ZIC3 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 216/418 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs766420888; called by muse, varscan2
- ZNF585A | c.749C>T p.A250V (on ENST00000292841 / NM_001288800.2; = p.A195V on NM_152655.3) | Missense Mutation (SNP) | VAF 81/348 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1389506878; called by muse, mutect2, varscan2
- ADGRG1 | c.999C>A p.F333L | Missense Mutation (SNP) | VAF 182/432 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- AVPR1A | c.1114A>G p.K372E | Missense Mutation (SNP) | VAF 256/539 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CLOCK | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 99/376 reads (26%) | called by muse, varscan2
- DNMT3A | c.1585G>T p.D529Y | Missense Mutation (SNP) | VAF 195/349 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC2 | c.4201C>A p.Q1401K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.204); called by mutect2, varscan2
- ITGAV | c.1450T>A p.L484I | Missense Mutation (SNP) | VAF 147/440 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- LGALS2 | c.146_147del p.R49Lfs*40 | Frame Shift Del (DEL) | VAF 131/228 reads (57%) | called by mutect2, pindel, varscan2
- MCM3 | c.1474C>T p.L492F (on ENST00000229854 / NM_001366374.2; = p.L482F on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 182/545 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR8J2 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RASSF3 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 79/416 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RHBDL3 | c.111+1del p.X37_splice | Splice Site (DEL) | VAF 91/589 reads (15%) | called by mutect2, pindel, varscan2
- SETD7 | c.514del p.M173Cfs*12 | Frame Shift Del (DEL) | VAF 198/343 reads (58%) | called by mutect2, pindel, varscan2
- SMOC1 | c.979dup p.L327Pfs*8 | Frame Shift Ins (INS) | VAF 102/382 reads (27%) | called by mutect2, pindel, varscan2
- SYNE1 | c.2410T>C p.S804P (on ENST00000367255 / NM_182961.4; = p.S811P on NM_033071.3) | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNJ2 | c.3641G>A p.G1214E | Missense Mutation (SNP) | VAF 155/576 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- TENM2 | c.8230G>A p.G2744R (on ENST00000518659 / NM_001122679.2; = p.G2505R on NM_001080428.3) | Missense Mutation (SNP) | VAF 234/556 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF628 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 185/648 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF804A | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 64/383 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF99 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CAPN8 | c.234C>T p.P78= | Silent (SNP) | VAF 41/163 reads (25%) | called by muse, mutect2, varscan2
- EBF1 | c.225C>T p.Y75= | Silent (SNP) | VAF 266/593 reads (45%) | catalogued as rs998358011, COSV58182094; called by muse, mutect2, varscan2
- GOLGA6L10 | c.1323G>A p.L441= | Silent (SNP) | VAF 251/1355 reads (19%) | called by muse, varscan2
- KRT5 | c.516C>A p.I172= | Silent (SNP) | VAF 82/112 reads (73%) | called by mutect2, varscan2
- LHX2 | c.1200G>T p.T400= | Silent (SNP) | VAF 88/253 reads (35%) | catalogued as COSV101010044; called by muse, mutect2, varscan2
- LRRC58 | c.756T>A p.V252= | Silent (SNP) | VAF 150/427 reads (35%) | called by muse, mutect2, varscan2
- PLA2G4F | c.639C>T p.Y213= | Silent (SNP) | VAF 81/459 reads (18%) | catalogued as rs148006230; called by muse, mutect2, varscan2
- PSKH2 | c.114G>A p.A38= | Silent (SNP) | VAF 156/842 reads (19%) | catalogued as rs1394047432; called by muse, mutect2, varscan2
- SLC12A3 | c.1050G>A p.S350= | Silent (SNP) | VAF 76/450 reads (17%) | catalogued as rs752171513, COSV52633423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.19350T>C p.P6450= (on ENST00000591111; = p.P5523= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/223 reads (27%) | called by muse, mutect2, varscan2
- URB1 | c.2145A>G p.T715= | Silent (SNP) | VAF 161/202 reads (80%) | called by muse, mutect2, varscan2
